Somatic mutation profile of tumor specimen TCGA-2G-AAL7-01A (aliquot TCGA-2G-AAL7-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAL7, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 32.6 years (11,917 days).
Specimen TCGA-2G-AAL7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 757c62c8-3807-43a5-80ab-8e7924b86c8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAL7-10A (Blood Derived Normal), aliquot TCGA-2G-AAL7-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/951f2abf-4817-4544-838a-9dad4e6d1cb5

The open-access MAF lists 24 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 17, Silent 5, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAC1 | c.101C>G p.P34R | Missense Mutation (SNP) | VAF 17/103 reads (17%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV61822860, COSV61823271; called by muse, mutect2, varscan2
- ACSM2A | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.483); catalogued as COSV54586343; called by muse, mutect2, varscan2
- AMMECR1 | c.229G>T p.G77C | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.599); catalogued as rs1290770764; called by muse, mutect2
- CLK3 | c.835C>T p.R279C (on ENST00000395066 / NM_001130028.1; = p.R131C on NM_003992.4) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs1567143428; called by muse, mutect2, varscan2
- FCGR2C | c.218C>A p.T73N | Missense Mutation (SNP) | VAF 132/203 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as COSV63438522; called by muse, mutect2, varscan2
- LARP7 | c.552+2dup p.X184_splice | Splice Site (INS) | VAF 27/104 reads (26%) | catalogued as rs758212893; called by mutect2, pindel, varscan2
- TACSTD2 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs766710867; called by muse, mutect2, varscan2
- CCN3 | c.915T>G p.N305K | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- CCT8L2 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- CHMP2A | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- CLK1 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 70/245 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRB1 | c.1729G>T p.A577S | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- KLHDC8A | c.813T>G p.F271L | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- LYST | c.8348C>T p.P2783L | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OTUB1 | c.339-7C>A | Splice Region (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- POTEA | c.460C>G p.H154D | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- RING1 | c.825G>T p.K275N | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.362); called by muse, mutect2
- TRIM37 | c.1366C>G p.P456A | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZC3H4 | c.3484G>A p.E1162K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- AC011448.1 | c.288C>A p.I96= | Silent (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- HMBS | c.66C>T p.R22= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs531691068, CS962736; called by muse, mutect2, varscan2
- KLHL13 | c.1155C>T p.A385= | Silent (SNP) | VAF 58/148 reads (39%) | catalogued as rs1009919556; called by muse, mutect2, varscan2
- TEX13A | c.1029G>A p.L343= | Silent (SNP) | VAF 34/112 reads (30%) | called by muse, mutect2, varscan2
- USP5 | c.385C>T p.L129= | Silent (SNP) | VAF 36/247 reads (15%) | called by muse, mutect2, varscan2
